Somatic mutation profile of tumor specimen TCGA-V5-AASX-01A (aliquot TCGA-V5-AASX-01A-11D-A387-09) from TCGA case TCGA-V5-AASX, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; Tumor grade: G2; Age at diagnosis: 74.1 years (27,081 days).
Specimen TCGA-V5-AASX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6f6bcd1a-a6a9-40d5-b6ce-2aa0df36dab6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-V5-AASX-10A (Blood Derived Normal), aliquot TCGA-V5-AASX-10A-01D-A38A-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/441da8bd-5d41-4535-baba-26a7dcb7c731

The open-access MAF lists 267 somatic variants for this specimen: 200 protein-altering or splice-affecting, 60 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 177, Silent 60, Nonsense Mutation 11, Intron 5, Frame Shift Del 4, Splice Site 3, Frame Shift Ins 2, In Frame Del 1, 3'Flank 1, RNA 1, Splice Region 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4384_4385del p.K1462Efs*6 | Frame Shift Del (DEL) | VAF 9/39 reads (23%) | catalogued as rs1554085846; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- NAP1L3 | c.1505A>G p.K502R | Missense Mutation (SNP) | VAF 7/37 reads (19%) | hotspot (GDC flag); SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs778332322, COSV59073839, COSV59074072, COSV59075074; called by muse, mutect2, varscan2
- TP53 | c.647T>A p.V216E | Missense Mutation (SNP) | VAF 12/48 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057520004, COSV52676908, COSV52856938, COSV52866969, COSV53036902; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ABCA12 | c.6322T>A p.F2108I (on ENST00000272895 / NM_173076.3; = p.F1790I on NM_015657.3) | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV55958390, COSV99790447; called by muse, mutect2, varscan2
- ADAMTS20 | c.2989T>C p.F997L | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.036); catalogued as COSV101166067; called by muse, mutect2, varscan2
- ADGRB1 | c.2093G>A p.R698Q | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.658); catalogued as rs774003073; called by muse, mutect2, varscan2
- AHDC1 | c.3187G>A p.V1063I | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.173); catalogued as rs1557659784; called by muse, varscan2
- AHNAK2 | c.1520G>A p.R507H | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1437160293, COSV60918612; called by muse, mutect2, varscan2
- AMER3 | c.209C>T p.A70V | Missense Mutation (SNP) | VAF 10/94 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.007); catalogued as rs200636300, COSV100366224, COSV58467211; called by muse, mutect2
- ANKK1 | c.2158G>A p.V720I | Missense Mutation (SNP) | VAF 8/108 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1164975652, COSV58273270; called by muse, mutect2
- ANTXR1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 11/91 reads (12%) | SIFT tolerated (0.52); PolyPhen benign (0.001); catalogued as rs762884429, COSV58012327; called by muse, mutect2, varscan2
- ASTN1 | c.1470G>T p.K490N | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.354); catalogued as COSV56085408; called by muse, mutect2
- BCOR | c.3907G>A p.G1303S (on ENST00000378444 / NM_001123385.2; = p.G1269S on NM_017745.6) | Missense Mutation (SNP) | VAF 10/41 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.063); catalogued as rs777973496; called by muse, mutect2, varscan2
- CACNA2D4 | c.1063C>T p.R355* | Nonsense Mutation (SNP) | VAF 9/48 reads (19%) | catalogued as rs369451253, COSV104383153, COSV99766212; called by muse, mutect2, varscan2
- CCDC74A | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV54605377, COSV99723645; called by muse, mutect2, varscan2
- CD300A | c.308G>A p.C103Y | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs373168457; called by muse, mutect2, varscan2
- CDH2 | c.2629A>C p.S877R | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99296229; called by muse, mutect2, varscan2
- CDH9 | c.487T>G p.L163V | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV50253829, COSV99145286, COSV99163241; called by muse, mutect2, varscan2
- CNTN5 | c.2053A>C p.S685R | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.325); catalogued as COSV54331769; called by muse, mutect2, varscan2
- COL24A1 | c.271G>A p.E91K | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.04); PolyPhen benign (0.154); catalogued as rs758503239, COSV65304236; called by muse, mutect2, varscan2
- CPS1 | c.562C>A p.Q188K | Missense Mutation (SNP) | VAF 6/87 reads (7%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV51802685; called by muse, mutect2
- CRYBB1 | c.23C>T p.S8L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0); catalogued as rs374176492; called by muse, mutect2, varscan2
- CST1 | c.339G>C p.Q113H | Missense Mutation (SNP) | VAF 20/185 reads (11%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.976); catalogued as COSV100494436, COSV59054967, COSV59056403; called by muse, mutect2, varscan2
- CYB561D2 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 16/69 reads (23%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs777306249; called by muse, mutect2, varscan2
- DBNL | c.896G>A p.R299K (on ENST00000448521 / NM_001014436.3; = p.R300K on NM_014063.7) | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as rs759617797; called by mutect2, varscan2
- DCDC1 | c.4939C>T p.P1647S (on ENST00000597505 / NM_001367979.1; = p.P754S on NM_020869.3) | Missense Mutation (SNP) | VAF 6/57 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.22); catalogued as rs781321680; called by muse, mutect2, varscan2
- DDX56 | c.511_513del p.L171del | In Frame Del (DEL) | VAF 6/50 reads (12%) | catalogued as rs763738678; called by pindel, varscan2
- DGKG | c.1453T>G p.F485V | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as COSV53962365; called by muse, mutect2
- DLG2 | c.760G>A p.E254K | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.562); catalogued as COSV99712073; called by muse, mutect2
- DOCK4 | c.502G>A p.A168T | Missense Mutation (SNP) | VAF 6/50 reads (12%) | SIFT tolerated (0.4); PolyPhen benign (0.03); catalogued as rs368007201; called by muse, mutect2, varscan2
- DTD2 | c.373C>G p.L125V | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT tolerated (0.13); PolyPhen benign (0.257); catalogued as rs762142726, COSV60427732; called by muse, mutect2
- DTYMK | c.448C>T p.R150C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs762448283; called by mutect2, varscan2
- DUSP22 | c.371G>A p.C124Y | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (0.68); PolyPhen benign (0.115); catalogued as rs928397166, COSV60525832; called by muse, mutect2, varscan2
- EFHD1 | c.677G>A p.R226H | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs761223584, COSV99898393; called by muse, mutect2, varscan2
- ELP1 | c.707C>T p.P236L | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.446); catalogued as rs374008013; called by muse, mutect2, varscan2
- EPHA5 | c.1364G>A p.R455Q | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.019); catalogued as rs1349813115, COSV99902386; called by muse, mutect2
- EXD2 | c.1508G>A p.R503H (on ENST00000312994 / NM_001193362.1; = p.R378H on NM_018199.3) | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs138036015; called by muse, mutect2, varscan2
- EXOSC4 | c.353G>A p.R118H | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.08); PolyPhen benign (0.424); catalogued as rs1474429068; called by muse, mutect2, varscan2
- FAM160A2 | c.1949G>A p.R650H (on ENST00000449352 / NM_001098794.2; = p.R664H on NM_032127.4) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.011); catalogued as rs777911426; called by muse, mutect2, varscan2
- FOXO1 | c.1082G>A p.S361N | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV65427280; called by muse, mutect2
- FRY | c.1717G>A p.E573K | Missense Mutation (SNP) | VAF 4/57 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.853); catalogued as COSV100969822; called by muse, mutect2
- FUS | c.136G>C p.D46H | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.417); catalogued as COSV54215643; called by muse, mutect2
- GLIS1 | c.1357G>A p.G453R | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.535); catalogued as rs538030086; called by muse, mutect2, varscan2
- GPR161 | c.907C>T p.P303S | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.056); catalogued as rs1410157372; called by muse, mutect2
- GUCY2D | c.2381T>G p.L794R | Missense Mutation (SNP) | VAF 5/42 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV99644408; called by muse, mutect2, varscan2
- H2BC3 | c.340G>A p.E114K | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.003); catalogued as COSV63551149; called by muse, mutect2
- HKDC1 | c.2177C>T p.T726M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs770837285, COSV63576408, COSV63579796; called by muse, mutect2, varscan2
- IGFBP3 | c.439G>A p.G147S | Missense Mutation (SNP) | VAF 7/35 reads (20%) | SIFT tolerated (0.71); PolyPhen benign (0.01); catalogued as COSV51872488; called by muse, mutect2, varscan2
- IL34 | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.945); catalogued as rs779885656; called by muse, mutect2, varscan2
- IQGAP1 | c.4414G>A p.V1472M | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.634); catalogued as rs751120932; called by muse, mutect2, varscan2
- KANK4 | c.2542G>A p.V848I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.681); catalogued as rs746099288, COSV100443270; called by muse, mutect2, varscan2
- KCNA6 | c.515C>T p.P172L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as COSV54976048; called by muse, mutect2, varscan2
- KIF26B | c.4709C>T p.T1570I | Missense Mutation (SNP) | VAF 5/53 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs1034436630; called by muse, mutect2
- KRT36 | c.716G>A p.R239H | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.178); catalogued as rs1022248660; called by muse, mutect2, varscan2
- LCE2C | c.235C>T p.R79C | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as rs535714518, COSV64228279; called by muse, mutect2
- LRP2 | c.12512T>C p.L4171P | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99788224; called by muse, mutect2
- LRRC18 | c.35A>G p.K12R | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.286); catalogued as rs763222470, COSV53282559, COSV99631553; called by muse, mutect2, varscan2
- LRRK1 | c.5653G>A p.G1885S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (0.8); PolyPhen benign (0); catalogued as rs377202593; called by muse, mutect2
- LZTS2 | c.1000C>T p.R334* | Nonsense Mutation (SNP) | VAF 9/76 reads (12%) | catalogued as rs774508276; called by muse, mutect2, varscan2
- MAP2K4 | c.841C>T p.R281* | Nonsense Mutation (SNP) | VAF 5/68 reads (7%) | catalogued as COSV62255065; called by muse, mutect2
- MIEF1 | c.749G>A p.R250H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1282144302, COSV57478867; called by muse, mutect2, varscan2
- MMP2 | c.124G>A p.A42T | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs1016960822; called by muse, mutect2, varscan2
- MRPL47 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 16/164 reads (10%) | SIFT tolerated (0.62); PolyPhen benign (0.026); catalogued as rs865894945, COSV52021222; called by muse, mutect2
- MYH3 | c.5323G>A p.D1775N | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.923); catalogued as rs756851156; called by muse, mutect2, varscan2
- MYL4 | c.151G>A p.D51N | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.095); catalogued as rs772358836, COSV100733080; called by muse, mutect2, varscan2
- MYO16 | c.3802G>A p.V1268I | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs377315850, COSV100695852; called by muse, mutect2, varscan2
- NLRP7 | c.1330G>A p.D444N | Missense Mutation (SNP) | VAF 6/61 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.198); catalogued as COSV60175633; called by muse, mutect2
- OPRL1 | c.1021C>T p.R341W | Missense Mutation (SNP) | VAF 7/85 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as rs150300242, COSV100402214; called by muse, mutect2
- OR1L4 | c.43C>G p.L15V | Missense Mutation (SNP) | VAF 14/134 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.197); catalogued as COSV52339704; called by muse, mutect2
- OR51L1 | c.794G>A p.R265H | Missense Mutation (SNP) | VAF 9/98 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.93); catalogued as rs772362329; called by muse, mutect2
- PALM2AKAP2 | c.969C>G p.F323L (on ENST00000259318 / NM_001136562.3; = p.F554L on NM_007203.5) | Missense Mutation (SNP) | VAF 4/53 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.316); catalogued as COSV52182802; called by muse, mutect2
- PARP4 | c.2011G>A p.E671K | Missense Mutation (SNP) | VAF 7/59 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.624); catalogued as rs1236172123, COSV67963413; called by muse, mutect2, varscan2
- PCDHA2 | c.1169C>T p.T390M | Missense Mutation (SNP) | VAF 9/56 reads (16%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.19); catalogued as rs1170903796, COSV65364387; called by muse, mutect2, varscan2
- PCDHB6 | c.638C>T p.A213V | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99170961, COSV99173543; called by mutect2, varscan2
- PCDHGA5 | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 8/51 reads (16%) | catalogued as COSV54027796; called by muse, mutect2, varscan2
- PCLO | c.5234C>T p.P1745L | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764070940, COSV61659877; called by muse, mutect2, varscan2
- PCSK6 | c.2849G>A p.R950Q | Missense Mutation (SNP) | VAF 7/55 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.196); catalogued as rs764226144; called by muse, mutect2, varscan2
- PHACTR3 | c.459G>T p.Q153H | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0.259); catalogued as COSV63026545; called by muse, mutect2, varscan2
- PRAMEF15 | c.874A>G p.S292G | Missense Mutation (SNP) | VAF 36/306 reads (12%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.783); catalogued as rs1490024884; called by muse, varscan2
- PRPF4 | c.122G>T p.R41L (on ENST00000374198 / NM_001322267.2; = p.R42L on NM_004697.5) | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.644); catalogued as COSV100950717; called by muse, mutect2, varscan2
- RC3H2 | c.560G>T p.R187L | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV59012430; called by muse, mutect2, varscan2
- RIMS1 | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as rs777907746, COSV53477919, COSV99325333; called by mutect2, varscan2
- RNGTT | c.674G>A p.R225Q | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as rs757072486; called by muse, mutect2, varscan2
- ROBO2 | c.1978C>T p.R660C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs912032432, COSV59939608; called by muse, mutect2, varscan2
- RSPH10B | c.220G>A p.E74K | Missense Mutation (SNP) | VAF 20/304 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs762487952, COSV100521289; called by muse, mutect2
- RSPH6A | c.853G>A p.G285S | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.62); PolyPhen benign (0.038); catalogued as rs553772648, COSV55570404; called by muse, mutect2, varscan2
- SASH1 | c.2599G>A p.E867K | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as COSV66558873; called by muse, mutect2
- SEMA3D | c.176T>A p.I59N | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT tolerated (0.31); PolyPhen benign (0.02); catalogued as rs776110750; called by mutect2, varscan2
- SH2B1 | c.196C>T p.R66C | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.541); catalogued as rs760696398; called by mutect2, varscan2
- SLC35F1 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.771); catalogued as rs192702359, COSV64498812; called by muse, mutect2
- SRGAP2 | c.2755C>T p.R919W (on ENST00000624873 / NM_001170637.4; = p.R920W on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as rs570977025; called by muse, mutect2, varscan2
- TG | c.1489T>G p.F497V | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.411); catalogued as COSV55094466; called by muse, mutect2, varscan2
- TRIB1 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 4/42 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1199031481; called by muse, mutect2, varscan2
- TSPEAR | c.1665G>C p.Q555H | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV100554894; called by muse, mutect2, varscan2
- USH2A | c.4179A>C p.K1393N | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.34); PolyPhen benign (0.131); catalogued as COSV56385498, COSV56391080; called by muse, mutect2, varscan2
- USP2 | c.1432C>T p.R478C | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.041); catalogued as rs763624175, COSV52727261; called by mutect2, varscan2
- USP48 | c.2164A>G p.N722D | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.6); PolyPhen benign (0.014); catalogued as rs368720845; called by muse, mutect2, varscan2
- WT1 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.891); catalogued as COSV60078123; called by muse, mutect2, varscan2
- ZKSCAN8 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.65); PolyPhen probably damaging (0.992); catalogued as rs202039260, COSV57636706; called by muse, mutect2, varscan2
- ZNF143 | c.310G>C p.E104Q | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs1355274140; called by muse, mutect2
- ZNF548 | c.1471C>T p.H491Y | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.55); catalogued as COSV60241367; called by muse, mutect2
- ZNF791 | c.707G>C p.R236T | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs1367970209, COSV58481403; called by muse, mutect2
- ZSCAN1 | c.646G>A p.E216K | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.24); PolyPhen benign (0.086); catalogued as rs374458811; called by muse, mutect2, varscan2
- A4GALT | c.221C>A p.P74H | Missense Mutation (SNP) | VAF 21/123 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACVRL1 | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.224); called by muse, mutect2, varscan2
- ACYP1 | c.278C>T p.S93L | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- ADAD1 | c.866T>G p.L289R | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ADAM32 | c.2102T>G p.V701G | Missense Mutation (SNP) | VAF 17/90 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- AHNAK2 | c.2853A>C p.E951D | Missense Mutation (SNP) | VAF 16/210 reads (8%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.959); called by muse, mutect2
- AP002512.3 | c.601T>G p.L201V | Missense Mutation (SNP) | VAF 3/18 reads (17%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.702); called by muse, mutect2
- ARHGAP19 | c.997G>A p.D333N | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.913); called by muse, mutect2, varscan2
- ARHGAP5 | c.4120G>A p.V1374I (on ENST00000345122 / NM_001030055.2; = p.V1373I on NM_001173.3) | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.009); called by muse, mutect2
- ATP13A1 | c.2678G>T p.R893L | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- AURKC | c.512A>C p.N171T (on ENST00000302804 / NM_001015878.2; = p.N137T on NM_003160.3) | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CAPRIN2 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 21/46 reads (46%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- CDR1 | c.67G>A p.E23K | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- CEP135 | c.3012+1G>C p.X1004_splice | Splice Site (SNP) | VAF 9/33 reads (27%) | called by muse, mutect2
- CSMD3 | c.10546T>G p.L3516V (on ENST00000297405 / NM_001363185.1; = p.L3347V on NM_052900.3) | Missense Mutation (SNP) | VAF 9/79 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- CTR9 | c.1249G>C p.E417Q | Missense Mutation (SNP) | VAF 10/112 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2
- CUTC | c.243G>T p.M81I | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.63); called by muse, mutect2
- CWF19L2 | c.1430C>T p.A477V | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- DNAH14 | c.777T>G p.N259K (on ENST00000445597; = p.N132K on NM_144989.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); called by muse, mutect2
- DNAJC21 | c.105T>A p.N35K | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- DOP1A | c.3448C>T p.Q1150* | Nonsense Mutation (SNP) | VAF 6/62 reads (10%) | called by muse, mutect2, varscan2
- DYNC1I1 | c.982T>G p.F328V | Missense Mutation (SNP) | VAF 13/105 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.359); called by muse, mutect2, varscan2
- DYNC2H1 | c.5907A>T p.L1969F | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- EPB41L4B | c.1777A>G p.K593E | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.836); called by muse, mutect2
- EPHA4 | c.1304C>T p.T435I | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPHB4 | c.2502A>T p.E834D | Missense Mutation (SNP) | VAF 7/79 reads (9%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.993); called by muse, mutect2
- ERC1 | c.2682G>T p.K894N (on ENST00000360905 / NM_178040.4; = p.K866N on NM_178039.4) | Missense Mutation (SNP) | VAF 11/83 reads (13%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.828); called by muse, mutect2, varscan2
- FBXL20 | c.492G>A p.L164= | Splice Region (SNP) | VAF 11/140 reads (8%) | called by muse, mutect2
- FIBCD1 | c.855dup p.Q286Sfs*54 | Frame Shift Ins (INS) | VAF 12/99 reads (12%) | called by mutect2, pindel, varscan2
- FRA10AC1 | c.637G>A p.E213K | Missense Mutation (SNP) | VAF 8/82 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.079); called by muse, mutect2
- FREM2 | c.8953G>C p.V2985L | Missense Mutation (SNP) | VAF 14/89 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- GAPDH | c.172G>A p.G58S | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.141); called by muse, mutect2
- GPR32 | c.912G>T p.L304F | Missense Mutation (SNP) | VAF 5/90 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- GRIK1 | c.431A>T p.D144V | Missense Mutation (SNP) | VAF 8/51 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- HAS3 | c.1375G>A p.A459T | Missense Mutation (SNP) | VAF 7/53 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.205); called by muse, mutect2, varscan2
- HID1 | c.711T>G p.F237L | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT tolerated (0.16); PolyPhen benign (0.029); called by muse, mutect2
- HMCN1 | c.12809C>A p.S4270* | Nonsense Mutation (SNP) | VAF 15/82 reads (18%) | called by muse, mutect2, varscan2
- IL13RA2 | c.669C>G p.I223M | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- INTS10 | c.1207C>T p.L403F | Missense Mutation (SNP) | VAF 9/82 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.745); called by muse, mutect2, varscan2
- ITPR1 | c.2032G>C p.E678Q (on ENST00000354582; = p.E663Q on NM_002222.7) | Missense Mutation (SNP) | VAF 17/104 reads (16%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IVL | c.844C>A p.Q282K | Missense Mutation (SNP) | VAF 55/166 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.077); called by muse, mutect2, varscan2
- KCNU1 | c.2635G>T p.G879* | Nonsense Mutation (SNP) | VAF 10/87 reads (11%) | called by muse, mutect2, varscan2
- KCNV1 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.157); called by muse, mutect2, varscan2
- KDM5B | c.2913G>C p.W971C | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); called by muse, mutect2
- KRTAP27-1 | c.351A>C p.Q117H | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.983); called by muse, varscan2
- KRTAP27-1 | c.312T>A p.S104R | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.23); PolyPhen benign (0.021); called by muse, varscan2
- LGALS4 | c.966G>C p.Q322H | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT tolerated (0.35); PolyPhen benign (0.019); called by muse, mutect2
- LGI1 | c.176G>C p.R59T | Missense Mutation (SNP) | VAF 5/82 reads (6%) | SIFT tolerated (0.38); PolyPhen benign (0.007); called by muse, mutect2
- LONRF1 | c.1090C>T p.L364F | Missense Mutation (SNP) | VAF 23/127 reads (18%) | SIFT tolerated (0.7); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRTM4 | c.602T>G p.F201C | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- MAGED2 | c.1707C>A p.F569L | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); called by muse, mutect2, varscan2
- MYH10 | c.2359A>C p.T787P | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO7B | c.2603G>T p.G868V | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NAP1L1 | c.630+1G>A p.X210_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | called by muse, mutect2, varscan2
- NLK | c.925C>T p.P309S | Missense Mutation (SNP) | VAF 10/104 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- NT5C1B | c.1del p.M1? | Frame Shift Del (DEL) | VAF 14/142 reads (10%) | called by mutect2, pindel
- NUMBL | c.546G>C p.E182D | Missense Mutation (SNP) | VAF 9/100 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.172); called by muse, mutect2
- OR4A16 | c.893dup p.N298Kfs*5 | Frame Shift Ins (INS) | VAF 8/46 reads (17%) | called by mutect2, pindel, varscan2
- OR51Q1 | c.668T>G p.I223S | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PCLO | c.5980A>T p.R1994* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | called by muse, mutect2, varscan2
- PITPNM2 | c.3628T>G p.S1210A | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PKD1L2 | c.2521A>G p.T841A | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PRDM2 | c.2615A>C p.Q872P | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.731); called by muse, mutect2, varscan2
- PREX2 | c.2834T>G p.V945G | Missense Mutation (SNP) | VAF 10/109 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PRRC2B | c.4672G>T p.V1558L | Missense Mutation (SNP) | VAF 5/78 reads (6%) | SIFT tolerated (0.13); PolyPhen benign (0.049); called by muse, mutect2
- PTPRS | c.1702G>A p.E568K | Missense Mutation (SNP) | VAF 9/73 reads (12%) | SIFT tolerated (0.63); PolyPhen benign (0.088); called by muse, mutect2
- RARB | c.254A>G p.Y85C (on ENST00000383772 / NM_001290216.2; = p.Y78C on NM_000965.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 6/89 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- RBMXL1 | c.451A>T p.R151* | Nonsense Mutation (SNP) | VAF 11/81 reads (14%) | called by muse, mutect2, varscan2
- REXO1 | c.3621C>A p.H1207Q | Missense Mutation (SNP) | VAF 6/62 reads (10%) | SIFT tolerated (0.18); PolyPhen benign (0.089); called by mutect2, varscan2
- RPL36 | c.175G>T p.E59* | Nonsense Mutation (SNP) | VAF 9/104 reads (9%) | called by muse, mutect2
- RYR1 | c.13696C>T p.L4566F | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- SFRP4 | c.307C>T p.R103C | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- SLCO1B1 | c.1184A>T p.Y395F | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- SLCO4A1 | c.1117C>T p.P373S | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.908); called by muse, mutect2
- SLFN11 | c.121C>A p.Q41K | Missense Mutation (SNP) | VAF 27/115 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- SMC1B | c.565_566insCAA p.K188_K189insT | In Frame Ins (INS) | VAF 8/69 reads (12%) | called by mutect2, pindel, varscan2
- SNX13 | c.1509C>A p.F503L | Missense Mutation (SNP) | VAF 3/49 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SYT16 | c.733G>T p.E245* | Nonsense Mutation (SNP) | VAF 15/63 reads (24%) | called by muse, mutect2, varscan2
- TPTE | c.567-1G>T p.X189_splice (on ENST00000618007 / NM_199261.4; = p.X171_splice on NM_199259.4) | Splice Site (SNP) | VAF 12/138 reads (9%) | called by muse, mutect2
- TRAPPC11 | c.2573C>T p.S858F | Missense Mutation (SNP) | VAF 9/91 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.358); called by muse, mutect2
- TRGV8 | c.109G>T p.A37S | Missense Mutation (SNP) | VAF 13/90 reads (14%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- TRPM3 | c.481T>A p.S161T (on ENST00000357533 / NM_001366142.2; = p.S6T on NM_020952.6) | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); called by muse, mutect2, varscan2
- TRRAP | c.5647G>A p.G1883R (on ENST00000359863 / NM_001244580.1; = p.G1865R on NM_003496.3) | Missense Mutation (SNP) | VAF 12/70 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TTN | c.11760A>C p.K3920N (on ENST00000591111; = p.K3874N on NM_003319.4) | Missense Mutation (SNP) | VAF 8/62 reads (13%) | called by muse, mutect2, varscan2
- UBQLN3 | c.632T>G p.L211R | Missense Mutation (SNP) | VAF 9/59 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- UHRF1BP1L | c.3472G>T p.V1158L | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT tolerated (0.44); PolyPhen benign (0.007); called by muse, mutect2
- VGF | c.1189_1190del p.R397Gfs*60 | Frame Shift Del (DEL) | VAF 7/51 reads (14%) | called by pindel, varscan2
- WASF2 | c.1184C>T p.P395L | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT tolerated (0.67); PolyPhen probably damaging (0.996); called by muse, varscan2
- XIRP2 | c.3240A>T p.Q1080H (on ENST00000628543; = p.Q1255H on NM_152381.6) | Missense Mutation (SNP) | VAF 10/71 reads (14%) | SIFT tolerated (0.09); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- XPNPEP1 | c.1154G>A p.C385Y | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- XXYLT1 | c.1082G>A p.R361K | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT tolerated (0.38); PolyPhen benign (0.038); called by muse, mutect2
- ZC3H18 | c.1999G>A p.E667K | Missense Mutation (SNP) | VAF 7/68 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ZNF292 | c.262del p.A88Pfs*12 | Frame Shift Del (DEL) | VAF 19/83 reads (23%) | called by mutect2, pindel, varscan2
- ZNF484 | c.1259C>T p.A420V | Missense Mutation (SNP) | VAF 8/71 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF676 | c.171G>T p.E57D (on ENST00000650058; = p.E25D on NM_001001411.3) | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.801); called by muse, mutect2, varscan2
- ZNF804B | c.450T>G p.I150M | Missense Mutation (SNP) | VAF 5/63 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.086); called by muse, mutect2
- ZNF813 | c.1046A>G p.H349R | Missense Mutation (SNP) | VAF 21/141 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA13 | c.14478C>T p.R4826= | Silent (SNP) | VAF 17/69 reads (25%) | catalogued as rs375778185; called by muse, mutect2, varscan2
- ADAD2 | c.1689C>T p.L563= (on ENST00000315906 / NM_001145400.2; = p.L645= on NM_139174.4) | Silent (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- AJAP1 | c.690G>A p.T230= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as rs1332357311; called by muse, mutect2, varscan2
- AK9 | c.3144C>T p.N1048= | Silent (SNP) | VAF 10/122 reads (8%) | catalogued as rs151316525; called by muse, mutect2
- AMACR | c.882G>T p.V294= | Silent (SNP) | VAF 6/70 reads (9%) | catalogued as COSV99672818; called by muse, mutect2
- AMOTL2 | c.24G>A p.S8= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs772176756; called by mutect2, varscan2
- APOB | c.8373T>G p.A2791= | Silent (SNP) | VAF 19/63 reads (30%) | called by muse, mutect2, varscan2
- BACH2 | c.2268G>A p.A756= | Silent (SNP) | VAF 10/62 reads (16%) | catalogued as rs776040980, COSV57596829; called by mutect2, varscan2
- C10orf71 | c.2046T>G p.P682= | Silent (SNP) | VAF 9/40 reads (23%) | called by muse, mutect2, varscan2
- CAMSAP1 | c.909C>T p.L303= | Silent (SNP) | VAF 9/64 reads (14%) | called by muse, mutect2, varscan2
- CAMSAP2 | c.1377C>A p.I459= (on ENST00000236925 / NM_001297707.2; = p.I448= on NM_203459.3) | Silent (SNP) | VAF 6/60 reads (10%) | called by muse, mutect2
- CELF2 | c.843G>A p.Q281= (on ENST00000416382 / NM_001025077.3; = p.Q288= on NM_006561.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 7/37 reads (19%) | called by muse, mutect2, varscan2
- CTNND2 | c.1104G>A p.A368= | Silent (SNP) | VAF 12/51 reads (24%) | called by muse, mutect2, varscan2
- EEF1D | c.672C>T p.D224= | Silent (SNP) | VAF 10/54 reads (19%) | catalogued as rs752074825; called by muse, varscan2
- EPHA5 | c.2136C>A p.G712= | Silent (SNP) | VAF 9/139 reads (6%) | catalogued as COSV56639710; called by muse, mutect2
- FDPS | c.696G>A p.Q232= | Silent (SNP) | VAF 10/73 reads (14%) | called by muse, mutect2, varscan2
- FGF18 | c.477G>A p.P159= | Silent (SNP) | VAF 5/37 reads (14%) | catalogued as rs768567377, COSV51125407; called by muse, mutect2, varscan2
- FREM1 | c.5385T>G p.S1795= | Silent (SNP) | VAF 24/112 reads (21%) | called by muse, mutect2, varscan2
- FRMPD4 | c.2241C>T p.D747= | Silent (SNP) | VAF 6/26 reads (23%) | catalogued as rs769972556, COSV66216986; called by muse, mutect2, varscan2
- GBE1 | c.390G>A p.Q130= | Silent (SNP) | VAF 12/99 reads (12%) | catalogued as COSV70102001; called by muse, mutect2, varscan2
- GREM2 | c.414C>T p.P138= | Silent (SNP) | VAF 9/64 reads (14%) | catalogued as rs1464539244; called by muse, mutect2, varscan2
- HLA-A | c.903T>G p.S301= | Silent (SNP) | VAF 18/204 reads (9%) | catalogued as COSV65141404; called by muse, mutect2
- HMCN1 | c.11997C>G p.V3999= | Silent (SNP) | VAF 6/82 reads (7%) | called by muse, mutect2
- HNRNPH3 | c.135G>A p.G45= | Silent (SNP) | VAF 9/85 reads (11%) | called by muse, mutect2, varscan2
- IBTK | c.1722C>G p.L574= | Silent (SNP) | VAF 3/45 reads (7%) | called by muse, mutect2
- KHDRBS2 | c.75G>A p.S25= | Silent (SNP) | VAF 7/55 reads (13%) | catalogued as rs1267777001, COSV55430587; called by muse, mutect2, varscan2
- KLHDC1 | c.453A>G p.Q151= | Silent (SNP) | VAF 7/120 reads (6%) | called by muse, mutect2
- KRTAP4-4 | c.177C>A p.T59= | Silent (SNP) | VAF 33/312 reads (11%) | catalogued as rs780684009; called by muse, mutect2
- LEPR | c.2829T>G p.L943= | Silent (SNP) | VAF 9/45 reads (20%) | called by muse, mutect2, varscan2
- LRP1B | c.11616T>C p.N3872= | Silent (SNP) | VAF 7/70 reads (10%) | catalogued as COSV67190794; called by muse, mutect2
- MEGF8 | c.6996C>T p.D2332= (on ENST00000251268 / NM_001271938.2; = p.D2265= on NM_001410.3) | Silent (SNP) | VAF 5/39 reads (13%) | called by muse, mutect2
- MICALL2 | c.69C>T p.I23= | Silent (SNP) | VAF 14/111 reads (13%) | called by muse, mutect2, varscan2
- MTMR9 | c.486C>T p.V162= | Silent (SNP) | VAF 30/129 reads (23%) | catalogued as rs1340655270; called by muse, mutect2, varscan2
- NEO1 | c.4149A>C p.P1383= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- NFYC | c.1376G>A p.*459= (on ENST00000308733 / NM_001308114.1; = p.*336= on NM_014223.5) | Silent (SNP) | VAF 9/65 reads (14%) | catalogued as rs1270233238, COSV58125476; called by muse, mutect2, varscan2
- NLRC4 | c.648C>T p.L216= | Silent (SNP) | VAF 9/71 reads (13%) | called by muse, mutect2, varscan2
- OGFR | c.1917G>A p.S639= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as rs1230597518; called by muse, mutect2, varscan2
- OPRPN | c.48C>T p.F16= | Silent (SNP) | VAF 9/77 reads (12%) | called by muse, mutect2, varscan2
- OR10K2 | c.315C>T p.L105= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as rs1442205970, COSV100149683; called by muse, mutect2
- OR10Z1 | c.183C>A p.L61= | Silent (SNP) | VAF 11/106 reads (10%) | called by muse, mutect2
- OR4Q3 | c.525G>T p.L175= | Silent (SNP) | VAF 28/111 reads (25%) | called by muse, mutect2, varscan2
- OXGR1 | c.840C>T p.I280= | Silent (SNP) | VAF 10/67 reads (15%) | catalogued as rs754641161; called by muse, mutect2, varscan2
- PCDHGA6 | c.1869G>A p.T623= | Silent (SNP) | VAF 9/101 reads (9%) | catalogued as rs1032808913; called by muse, mutect2
- PDLIM3 | c.186C>T p.P62= (on ENST00000284770 / NM_001257963.1; = p.P229= on NM_014476.6) | Silent (SNP) | VAF 13/62 reads (21%) | catalogued as rs753543916, COSV52977944, COSV99507967; called by muse, mutect2, varscan2
- PPP1R21 | c.975C>T p.I325= | Silent (SNP) | VAF 8/74 reads (11%) | catalogued as rs751226971; called by muse, mutect2, varscan2
- PTPRM | c.78C>A p.G26= | Silent (SNP) | VAF 14/109 reads (13%) | called by muse, mutect2, varscan2
- RAI14 | c.207C>A p.L69= | Silent (SNP) | VAF 12/122 reads (10%) | catalogued as COSV54297649; called by muse, mutect2
- SH2D3C | c.888C>A p.L296= (on ENST00000314830 / NM_170600.3; = p.L139= on NM_005489.4) | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as COSV59119831; called by mutect2, varscan2
- SIK2 | c.2475G>A p.P825= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs1361998338; called by muse, mutect2, varscan2
- SMG1 | c.3775C>T p.L1259= | Silent (SNP) | VAF 48/509 reads (9%) | called by muse, mutect2
- SMPDL3B | c.753C>T p.F251= | Silent (SNP) | VAF 12/49 reads (24%) | called by muse, mutect2, varscan2
- ST8SIA3 | c.288G>A p.A96= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs781529555; called by muse, mutect2, varscan2
- TNR | c.1293G>T p.V431= | Silent (SNP) | VAF 15/55 reads (27%) | called by muse, mutect2, varscan2
- TRAPPC8 | c.1929C>T p.L643= | Silent (SNP) | VAF 8/67 reads (12%) | called by muse, mutect2, varscan2
- TRIM60 | c.1374C>T p.S458= | Silent (SNP) | VAF 13/86 reads (15%) | catalogued as rs756055313; called by muse, mutect2, varscan2
- TSHZ3 | c.81C>T p.D27= | Silent (SNP) | VAF 26/61 reads (43%) | catalogued as rs745775592; called by muse, mutect2, varscan2
- VPS13A | c.6618G>A p.Q2206= | Silent (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- WNT11 | c.483C>A p.L161= | Silent (SNP) | VAF 11/151 reads (7%) | called by muse, mutect2
- ZEB2 | c.2745C>A p.T915= | Silent (SNP) | VAF 6/52 reads (12%) | called by muse, mutect2, varscan2
- ZNF71 | c.1407C>T p.G469= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as rs754639538, COSV60150041; called by muse, mutect2, varscan2
- BCAS3 | c.2075-4885G>C | Intron (SNP) | VAF 12/88 reads (14%) | called by muse, varscan2
- ENPP2 | c.973-2064C>A | Intron (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- KIF1B | c.2115+7187A>T | Intron (SNP) | VAF 16/41 reads (39%) | called by muse, mutect2, varscan2
- LRP1 | c.841+4194G>A | Intron (SNP) | VAF 9/43 reads (21%) | catalogued as rs1301366186; called by muse, mutect2, varscan2
- MARCHF1 | c.-322-85369A>C | Intron (SNP) | VAF 12/122 reads (10%) | called by muse, varscan2
- ROR2 | chr9:91722555 C>T | 3'Flank (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- SNORD108 | n.3T>G | RNA (SNP) | VAF 4/30 reads (13%) | called by muse, mutect2
